Somatic mutation profile of cancer-model specimen HCM-BROD-0955-C15-85B (3D Organoid, passage 5; aliquot HCM-BROD-0955-C15-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0955-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,191 days).
Specimen HCM-BROD-0955-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7769ffca-ec65-4962-a562-6bbb4b0485bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0955-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0955-C15-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/224ca6ee-ce29-4146-8969-d2c0b390cbd5

The open-access MAF lists 195 somatic variants for this specimen: 146 protein-altering or splice-affecting, 41 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 41, Nonsense Mutation 6, Intron 4, Frame Shift Del 4, In Frame Del 4, Frame Shift Ins 2, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 414/414 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3247C>G p.R1083G (on ENST00000506720 / NM_001322402.2; = p.R1015G on NM_015236.6) | Missense Mutation (SNP) | VAF 100/194 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV72230649; called by muse, mutect2, varscan2
- ALCAM | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs1354968351; called by muse, mutect2, varscan2
- ANK2 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 265/435 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1393086626, COSV52154632; called by muse, mutect2, varscan2
- ANK3 | c.10721G>A p.R3574H | Missense Mutation (SNP) | VAF 201/408 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs761460860; called by muse, mutect2, varscan2
- ANO3 | c.2834G>T p.R945L | Missense Mutation (SNP) | VAF 319/640 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56788908; called by muse, mutect2, varscan2
- ASXL3 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 178/369 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1348528374; called by muse, mutect2, varscan2
- BCOR | c.2514dup p.K839Qfs*5 | Frame Shift Ins (INS) | VAF 332/472 reads (70%) | catalogued as rs1394942244; called by mutect2, pindel, varscan2
- BRPF3 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 242/592 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1410764054; called by muse, mutect2, varscan2
- C10orf90 | c.1460T>G p.L487R | Missense Mutation (SNP) | VAF 190/405 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52958542, COSV99504562; called by muse, mutect2, varscan2
- CACNA1E | c.2828G>A p.S943N | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV62402371; called by muse, mutect2
- CDH24 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99943559; called by muse, mutect2
- CNTN3 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs778473765, COSV55166504, COSV55179966; called by muse, mutect2, varscan2
- CPSF1 | c.3163_3165del p.K1055del | In Frame Del (DEL) | VAF 321/533 reads (60%) | catalogued as rs1554863305; called by mutect2, pindel, varscan2
- CREB3L4 | c.658_660del p.K220del | In Frame Del (DEL) | VAF 79/560 reads (14%) | catalogued as rs778091329; called by pindel, varscan2
- CRP | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 180/913 reads (20%) | catalogued as COSV99660370, COSV99660464; called by muse, mutect2, varscan2
- CRP | c.364T>G p.S122A | Missense Mutation (SNP) | VAF 179/915 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs745569100; called by muse, mutect2, varscan2
- DYDC2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs994057331, COSV55472795; called by muse, mutect2, varscan2
- EN1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 345/521 reads (66%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.108); catalogued as COSV54630863, COSV99727391; called by muse, mutect2, varscan2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 392/635 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- FMN2 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs756685985; called by muse, mutect2, varscan2
- FMO1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as rs188375903, COSV61445337; called by muse, mutect2, varscan2
- GDPD5 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 179/616 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs770826317; called by muse, mutect2, varscan2
- GFI1B | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 185/766 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774517040, COSV59745449; called by muse, mutect2, varscan2
- GRM8 | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 90/171 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58829629, COSV58836480; called by muse, varscan2
- HSPA6 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 365/1059 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100553916; called by muse, mutect2, varscan2
- IRAG1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 124/953 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774827360, COSV70212166; called by muse, mutect2, varscan2
- KCNA6 | c.1141T>G p.F381V | Missense Mutation (SNP) | VAF 220/688 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54974572; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 154/531 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2, varscan2
- MAD1L1 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 268/889 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs779234549, COSV56233982; called by muse, mutect2, varscan2
- MAGI2 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62642519; called by muse, mutect2, varscan2
- MAPK4 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 151/333 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772337922, COSV101245835; called by muse, mutect2, varscan2
- MARCHF11 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 33/796 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1184046140; called by muse, mutect2
- MDGA1 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 394/741 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs1476206111; called by muse, mutect2, varscan2
- METTL25 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 232/478 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs761750644; called by muse, mutect2, varscan2
- MINK1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1198604179; called by muse, mutect2, varscan2
- MYO7A | c.5495G>A p.R1832Q | Missense Mutation (SNP) | VAF 102/539 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs372768607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.5290G>A p.A1764T (on ENST00000396087 / NM_001244963.2; = p.A1708T on NM_145117.5) | Missense Mutation (SNP) | VAF 152/604 reads (25%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.986); catalogued as rs769042839, COSV60661293; called by muse, mutect2, varscan2
- NRXN1 | c.3713C>G p.P1238R | Missense Mutation (SNP) | VAF 139/468 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60505644; called by muse, mutect2, varscan2
- OR2B2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV104408877; called by muse, mutect2
- PCDHGA2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 445/445 reads (100%) | catalogued as COSV53905469; called by muse, mutect2, varscan2
- PKD1L3 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 338/537 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs553586556, COSV58662972; called by muse, mutect2, varscan2
- PKN1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 495/496 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as rs746755914; called by muse, mutect2, varscan2
- RAB18 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63614048; called by muse, mutect2, varscan2
- RAVER2 | c.581A>G p.D194G | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1366147672; called by muse, mutect2, varscan2
- RELN | c.8174C>T p.S2725F | Missense Mutation (SNP) | VAF 154/1504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs138975709; called by muse, mutect2, varscan2
- RICTOR | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 318/587 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767673010; called by muse, mutect2
- SCN1A | c.3407C>T p.S1136L (on ENST00000303395 / NM_001202435.3; = p.S1125L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs746718015, COSV57668986; called by muse, mutect2, varscan2
- SCN5A | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 214/751 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs1455337011, CM1414690, COSV61141043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A6 | c.790T>C p.S264P | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV104371493; called by muse, mutect2, varscan2
- SORL1 | c.4598G>A p.R1533H | Missense Mutation (SNP) | VAF 76/476 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs759454929; called by muse, mutect2, varscan2
- SYNDIG1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 229/956 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs144760628; called by muse, mutect2, varscan2
- TCF7L2 | c.1157G>A p.R386Q (on ENST00000355995 / NM_001367943.1; = p.R363Q on NM_030756.5) | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as COSV53337947; called by muse, mutect2, varscan2
- TFAP2C | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 529/982 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV52373649; called by muse, mutect2, varscan2
- TLX3 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 82/658 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51541946; called by muse, mutect2, varscan2
- TNIK | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 378/580 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52677986; called by muse, mutect2, varscan2
- TNXB | c.6071G>A p.R2024H (on ENST00000647633; = p.R1777H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 268/615 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs767799073, COSV64482909; called by muse, mutect2, varscan2
- TPTE | c.1190T>C p.F397S (on ENST00000618007 / NM_199261.4; = p.F379S on NM_199259.4) | Missense Mutation (SNP) | VAF 154/840 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1300915060; called by muse, mutect2, varscan2
- TRPM6 | c.2029C>G p.L677V | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.338); catalogued as COSV62507627; called by muse, mutect2, varscan2
- WBP4 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 88/653 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1217383847; called by muse, mutect2, varscan2
- ZFAND4 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138384835; called by muse, mutect2, varscan2
- ZIC4 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 258/538 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV67170786; called by muse, mutect2, varscan2
- ZNF10 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 160/556 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs370466960; called by muse, mutect2, varscan2
- ZNF197 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs767682599, COSV60360205; called by muse, mutect2, varscan2
- ZNF316 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 38/1066 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs922206332; called by muse, mutect2
- ZNF91 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 131/134 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56090320; called by muse, mutect2, varscan2
- ADAT3 | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 36/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- AGFG2 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 178/1280 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASH1L | c.5777del p.R1926Kfs*83 | Frame Shift Del (DEL) | VAF 214/660 reads (32%) | called by mutect2, pindel, varscan2
- ATP10A | c.2324T>A p.L775H | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BIRC6 | c.11629C>T p.P3877S | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH2 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 307/309 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CDKN2A | c.300_305del p.G101_A102del | In Frame Del (DEL) | VAF 606/639 reads (95%) | called by pindel, varscan2*
- CEP164 | c.1468A>C p.T490P | Missense Mutation (SNP) | VAF 202/714 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); called by mutect2, varscan2
- COG2 | c.2084T>A p.L695* | Nonsense Mutation (SNP) | VAF 255/396 reads (64%) | called by muse, mutect2, varscan2
- COL11A1 | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CPNE8 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 167/168 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CUL4B | c.1777A>T p.I593L | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DGKI | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 156/313 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DIP2C | c.4301_4308del p.H1434Pfs*24 | Frame Shift Del (DEL) | VAF 190/206 reads (92%) | called by mutect2, pindel, varscan2
- DLG5 | c.1876del p.E626Rfs*7 | Frame Shift Del (DEL) | VAF 110/416 reads (26%) | called by mutect2, pindel, varscan2
- DNHD1 | c.12397G>A p.D4133N | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DOCK8 | c.4399A>G p.N1467D | Missense Mutation (SNP) | VAF 350/350 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EDA | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPEP | c.1709A>G p.Q570R | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLNC | c.5519A>G p.Y1840C | Missense Mutation (SNP) | VAF 161/325 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FRG2B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.056); called by muse, varscan2
- FSHR | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- FTO | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- FTO | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 18/563 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- GABRA5 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GCFC2 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 566/863 reads (66%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLI3 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 162/484 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 128/265 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP4 | c.1720C>G p.P574A | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- H2AC4 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 291/600 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.15046G>A p.A5016T | Missense Mutation (SNP) | VAF 76/1330 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- IGHE | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 507/826 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNS1 | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 619/1184 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT222 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP19-2 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 180/184 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LBX1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 215/482 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPI | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LYPLAL1 | c.323_325del p.E108del | In Frame Del (DEL) | VAF 68/290 reads (23%) | called by pindel, varscan2
- MAP2 | c.1592G>T p.S531I | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH6 | c.3746A>C p.K1249T | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NAV2 | c.6929A>T p.E2310V (on ENST00000396087 / NM_001244963.2; = p.E2251V on NM_145117.5) | Missense Mutation (SNP) | VAF 295/720 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NXPE2 | c.1500G>C p.E500D | Missense Mutation (SNP) | VAF 142/465 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- OR5D16 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 334/343 reads (97%) | SIFT deleterious (0.05); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OR8D1 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PDGFRA | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 34/716 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PHOX2B | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 225/506 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PKDCC | c.1170C>G p.H390Q | Missense Mutation (SNP) | VAF 358/516 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R12B | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP2R3A | c.1422G>T p.E474D | Missense Mutation (SNP) | VAF 136/266 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PWP1 | c.859T>G p.S287A | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- PYROXD1 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 120/189 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- R3HCC1L | c.2092A>G p.I698V (on ENST00000612478 / NM_001256619.2; = p.I684V on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RALGAPA1 | c.5501C>A p.A1834E | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RELN | c.2515T>C p.F839L | Missense Mutation (SNP) | VAF 63/635 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RNPC3 | c.1023_1027del p.N342* | Frame Shift Del (DEL) | VAF 136/220 reads (62%) | called by mutect2, pindel, varscan2
- RP1 | c.4121G>A p.S1374N | Missense Mutation (SNP) | VAF 158/305 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RTCB | c.626C>G p.A209G | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SBF2 | c.4241G>A p.W1414* | Nonsense Mutation (SNP) | VAF 198/198 reads (100%) | called by muse, mutect2, varscan2
- SBF2 | c.3484G>C p.A1162P | Missense Mutation (SNP) | VAF 240/241 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SELENBP1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 175/493 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC1A3 | c.1211T>C p.L404P | Missense Mutation (SNP) | VAF 381/897 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLMAP | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNW1 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 196/537 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- STON1 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 384/535 reads (72%) | called by muse, mutect2, varscan2
- STXBP5 | c.1937T>C p.F646S | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SZT2 | c.5276A>G p.E1759G (on ENST00000634258 / NM_001365999.1; = p.E1702G on NM_015284.4) | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- THEGL | c.98dup p.P34Afs*14 | Frame Shift Ins (INS) | VAF 139/577 reads (24%) | called by mutect2, pindel, varscan2
- TMEM132A | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 39/1242 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- TOP2B | c.2386T>C p.F796L (on ENST00000264331 / NM_001330700.2; = p.F791L on NM_001068.3) | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TRAV1-2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 364/713 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TRIM55 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.141); called by muse, mutect2
- TRPC4 | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 104/1262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TTBK1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 68/567 reads (12%) | called by muse, mutect2, varscan2
- TTC14 | c.1438A>C p.S480R | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TTC27 | c.1466T>G p.L489R | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2
- TTC28 | c.5104C>T p.P1702S | Missense Mutation (SNP) | VAF 188/382 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC7B | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 311/476 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- XPO4 | c.2376C>A p.F792L | Missense Mutation (SNP) | VAF 148/690 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZC3H3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 73/1418 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- ACTR8 | c.1449C>T p.A483= | Silent (SNP) | VAF 181/385 reads (47%) | catalogued as rs779325108; called by muse, mutect2, varscan2
- AHNAK2 | c.8841C>T p.D2947= | Silent (SNP) | VAF 318/952 reads (33%) | catalogued as rs751707241; called by muse, mutect2, varscan2
- AMN | c.96C>T p.V32= | Silent (SNP) | VAF 252/423 reads (60%) | catalogued as rs773494418, COSV100141572; called by muse, mutect2, varscan2
- ANKRD1 | c.135G>C p.L45= | Silent (SNP) | VAF 191/383 reads (50%) | catalogued as COSV63310939; called by muse, mutect2, varscan2
- ANKRD20A1 | c.36G>A p.Q12= | Silent (SNP) | VAF 16/499 reads (3%) | catalogued as rs1160376618; called by muse, mutect2
- ANKRD9 | c.408G>A p.L136= | Silent (SNP) | VAF 36/1192 reads (3%) | called by muse, mutect2
- CACNA1B | c.3357C>T p.S1119= | Silent (SNP) | VAF 363/715 reads (51%) | catalogued as rs200081614; called by mutect2, varscan2
- CARMIL2 | c.3051C>T p.R1017= | Silent (SNP) | VAF 171/405 reads (42%) | called by muse, mutect2, varscan2
- CASP1 | c.735G>T p.G245= (on ENST00000436863 / NM_033292.4; = p.G224= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 308/479 reads (64%) | called by muse, mutect2, varscan2
- CENPI | c.1251C>T p.F417= | Silent (SNP) | VAF 112/112 reads (100%) | called by muse, mutect2, varscan2
- CSMD3 | c.3021G>A p.T1007= (on ENST00000297405 / NM_001363185.1; = p.T903= on NM_052900.3) | Silent (SNP) | VAF 158/249 reads (63%) | catalogued as rs761435780, COSV52194726; called by muse, mutect2, varscan2
- DBF4 | c.1734G>A p.V578= | Silent (SNP) | VAF 158/252 reads (63%) | catalogued as COSV55996626; called by muse, mutect2, varscan2
- DLX6 | c.288C>T p.H96= | Silent (SNP) | VAF 552/1250 reads (44%) | catalogued as COSV50293748; called by muse, varscan2
- DOK5 | c.279T>A p.A93= | Silent (SNP) | VAF 45/629 reads (7%) | called by muse, mutect2
- EFTUD2 | c.2424C>A p.I808= | Silent (SNP) | VAF 159/721 reads (22%) | called by muse, mutect2, varscan2
- FAR2 | c.237C>T p.I79= | Silent (SNP) | VAF 136/356 reads (38%) | called by muse, mutect2, varscan2
- FBXL14 | c.609C>A p.G203= | Silent (SNP) | VAF 120/696 reads (17%) | called by muse, mutect2, varscan2
- FOXF2 | c.978C>T p.A326= | Silent (SNP) | VAF 674/1081 reads (62%) | called by muse, mutect2, varscan2
- FOXO1 | c.606C>T p.D202= | Silent (SNP) | VAF 370/1481 reads (25%) | catalogued as rs762028388; called by muse, mutect2, varscan2
- FSBP | c.93A>G p.E31= | Silent (SNP) | VAF 287/428 reads (67%) | catalogued as rs184283750; called by muse, mutect2, varscan2
- IGSF21 | c.54C>T p.I18= | Silent (SNP) | VAF 405/605 reads (67%) | called by muse, mutect2, varscan2
- KIF1B | c.2877G>A p.G959= (on ENST00000377086 / NM_001365952.1; = p.G913= on NM_015074.3) | Silent (SNP) | VAF 124/408 reads (30%) | called by muse, mutect2, varscan2
- LRRC30 | c.120G>A p.P40= | Silent (SNP) | VAF 164/504 reads (33%) | catalogued as rs1042712695, COSV67301239; called by muse, mutect2, varscan2
- LRRC52 | c.639A>G p.T213= | Silent (SNP) | VAF 139/437 reads (32%) | called by muse, mutect2, varscan2
- MAGEL2 | c.786G>A p.P262= | Silent (SNP) | VAF 491/733 reads (67%) | catalogued as rs772162359; called by muse, mutect2, varscan2
- MEI1 | c.495C>T p.I165= | Silent (SNP) | VAF 112/282 reads (40%) | catalogued as rs1383678325, COSV100300105; called by muse, mutect2, varscan2
- MYEF2 | c.1407G>A p.V469= | Silent (SNP) | VAF 228/228 reads (100%) | called by muse, mutect2, varscan2
- PCDH15 | c.3219A>C p.S1073= | Silent (SNP) | VAF 91/192 reads (47%) | called by muse, mutect2, varscan2
- PXDN | c.2529C>T p.D843= | Silent (SNP) | VAF 381/590 reads (65%) | catalogued as rs949156715; called by muse, mutect2, varscan2
- RASAL3 | c.1284G>A p.P428= | Silent (SNP) | VAF 1212/1656 reads (73%) | called by muse, mutect2, varscan2
- RBM26 | c.985C>T p.L329= | Silent (SNP) | VAF 23/424 reads (5%) | called by muse, mutect2
- RHPN1 | c.78G>A p.T26= | Silent (SNP) | VAF 294/438 reads (67%) | catalogued as rs760214238, COSV56648860; called by muse, mutect2, varscan2
- SHISA6 | c.837C>G p.T279= (on ENST00000409168 / NM_001173461.1; = p.T330= on NM_207386.4) | Silent (SNP) | VAF 301/699 reads (43%) | catalogued as rs796082499; called by muse, mutect2, varscan2
- SLC25A37 | c.45G>T p.R15= | Silent (SNP) | VAF 275/538 reads (51%) | called by muse, mutect2, varscan2
- SOX1 | c.828C>T p.L276= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs1239200884; called by muse, mutect2, varscan2
- TMEM200C | c.663C>T p.A221= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as rs759122765; called by muse, mutect2, varscan2
- TTC21A | c.3414G>A p.R1138= | Silent (SNP) | VAF 203/428 reads (47%) | catalogued as rs1299674121; called by muse, mutect2, varscan2
- TTLL10 | c.1566C>T p.C522= | Silent (SNP) | VAF 316/693 reads (46%) | catalogued as rs762946597; called by muse, mutect2, varscan2
- WDFY4 | c.6873A>G p.R2291= | Silent (SNP) | VAF 87/317 reads (27%) | called by muse, mutect2, varscan2
- ZIC1 | c.339A>G p.A113= | Silent (SNP) | VAF 210/573 reads (37%) | called by muse, mutect2, varscan2
- ZNF609 | c.3765C>T p.Y1255= | Silent (SNP) | VAF 118/248 reads (48%) | called by muse, mutect2, varscan2
- ARMC5 | c.1864+248C>T | Intron (SNP) | VAF 153/509 reads (30%) | catalogued as rs549737362; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943401 G>A | 3'Flank (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- DPP6 | c.244-140696C>T | Intron (SNP) | VAF 148/289 reads (51%) | catalogued as rs766391815, COSV59609173; called by muse, mutect2, varscan2
- ECE1 | c.139-55_139-47del | Intron (DEL) | VAF 156/701 reads (22%) | called by mutect2, pindel, varscan2
- FBRS | chr16:30659592 C>G | 5'Flank (SNP) | VAF 159/1103 reads (14%) | catalogued as rs1325958826; called by muse, mutect2, varscan2
- IGHG2 | chr14:105641895 C>G | 3'Flank (SNP) | VAF 96/302 reads (32%) | called by muse, mutect2
- NRG1 | chr8:31640053 C>T | 5'Flank (SNP) | VAF 156/237 reads (66%) | catalogued as rs1218204676; called by muse, mutect2, varscan2
- TMEM9B | c.441+52G>A | Intron (SNP) | VAF 350/350 reads (100%) | catalogued as rs1415596587, COSV58428076; called by muse, mutect2, varscan2
